Surgical pathology report (de-identified scan), TCGA case TCGA-12-3649, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-3649-01A (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

TCGA-12-3649

AP Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

Brain tumor.

GROSS EXAMINATION:

A. "Brain tissue (AF1)", received fresh for frozen section is a 2.5 x 1.5 x 1.2 cm fragment of pink-tan soft tissue. The representative section has been frozen as AF1 and the frozen section remnant is submitted in block A1. Additional representative sections are submitted in blocks A2, with the remainder retained in formalin.

B. "Brain tissue", received fresh and placed in formalin is a 3.7 x 3 x 2 cm aggregate of pink-tan soft tissue. Sectioning demonstrates a white-pink cut surface with focal areas of hemorrhage. Representative cross sections are submitted in blocks B1-3, with the remainder retained in formalin.

C. "Brain tissue", received fresh and placed in formalin is a 1 x 0.7 x 0.6 cm aggregate of pink-tan tissue. Representative section is submitted in block C1, with the remainder retained in formalin.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1- glioma, high grade [REDACTED].

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a malignant astrocytic neoplasm characterized by cytologic pleomorphism, mitotic figures, microvascular changes and pseudopalisading necrosis. On block B3, subarachnoid infiltration is evident.

DIAGNOSIS:

A. "BRAIN TISSUE" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

B. "BRAIN TISSUE" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

C. "BRAIN TISSUE" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

SUBARACHNOID INFILTRATION EVIDENT

COMMENT:

[REDACTED] NEUROPATHOLOGIST OF [REDACTED] AND THE ORIGINAL NEUROPATHOLOGIST OF THE FIRST BIOPSY, HAS REVIEWED THE SLIDES AND CONCURS WITH THE DIAGNOSES RENDERED.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary

[page 2 of 3]
tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (76% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - AMPLIFICATION (96% OF TUMOR CELLS EXHIBIT AMPLIFICATION)

CHROMOSOME 10 CENTROMERE - CENTROMERE LOSS (36% OF TUMOR CELLS EXHIBIT LOSS)

PTEN - ALLELIC LOSS (60% OF TUMOR CELLS EXHIBIT LOSS)

1p36 - INACT (NO LOSS)

1p32 - INTACT (NO LOSS)

19q13 - POLYSOMY (68% OF TUMOR CELLS EXHIBIT A RATIO FOR 19q13/19p13 OF LESS THAN 1.0)

9p21 - LOSS (58% OF TUMOR CELLS EXHIBIT LOSS)

CHROMOSOME 9 CENTROMERE - POLYSOMY (56% OF TUMOR CELLS EXHIBIT POLYSOMY)

FOR THE ASTROCYTIC MARKERS, 4 OF 4 MARKERS ARE ABNORMAL AND 9p21 EXHIBITS LOSS.

FOR THE OLIGODENDROGLIAL MARKERS, ALL LOCI ARE INTACT.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF [REDACTED] PATIENTS WITH GLIOBLASTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH 4 ABNORMAL MARKERS EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

BOTH FISH AND IMMUNOHISTOCHEMISTRY FOR PTEN REVEAL SIMILAR FINDINGS INDICATIVE OF LOSS OF PTEN STATUS.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING GLIOBLASTOMA (WHO GRADE IV; [REDACTED])

VEGF IMMUNOHISTOCHEMISTRY: NEGATIVE (2 x 5% = score 10).

PDGFR-A IMMUNOHISTOCHEMISTRY: FOCAL (30%) FOR CYTOPLASMIC AND/OR MEMBRANE REACTIVITY.

PDGFR-B IMMUNOHISTOCHEMISTRY: FOCAL (30%) OR NEGATIVE FOR CYTOPLASMIC AND/OR MEMBRANE REACTIVITY.

LEUCOCYTE COMMON ANTIGEN (LCA): 25% OF POSITIVE CELLS.

PROLIFERATION INDEX INTERPRETATION: HIGH PROLIFERATION INDEX (20% OF TUMOR CELLS EXHIBIT STAINING).

MGMT - NEGATIVE (10% OF TUMOR CELLS)

EGFR wt - POSITIVE (3+ IN 90% OF TUMOR CELLS)

[page 3 of 3]
EGFR VIII - NEGATIVE (0% OF TUMOR CELLS)

PTEN - LOSS (2+ IN 60% OF TUMOR CELLS)

S6 - POSITIVE (2+ IN 30% OF TUMOR CELLS)

AKT - NEGATIVE (2+ IN 10% OF TUMOR CELLS)

MAPK - POSITIVE (3+ IN 20% OF TUMOR CELLS)

Please see [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 3:

HAM 56 staining reveals a focally dense macrophage population consisting of approximately 25% of cells in regions about areas of necrosis. Remaining areas are largely negative for macrophages.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 5:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CKIT - POLYSOMY (89% OF TUMOR CELLS EXHIBIT POLYSOMY)

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

CI ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

Performed by: [REDACTED]

Ordering MD: [REDACTED]

Source: NCI Genomic Data Commons file 9f4f52d7-169c-4bca-9782-88d2c0faa2e7 (TCGA-12-3649.65889743-1E73-4812-9909-0711A1B68C2E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).